ALCHEMIST case ALCH-AEOY — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/14578aa6-068e-4213-826a-bb19a4c63066

Demographics
Sex at birth: male.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 85.4 years (31,184 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-AEOY-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-AEOY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-AEOY-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 40; Percent normal cells: 50; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
